Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7OY, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7OY-01A (Primary Tumor).

[page 1 of 8]
Age: years Sex: Male

Date Printed:
Date Collected:
Date Received:
Accession No:
Physician:
Copy to:

Surgical Pathology Report

Clinical Information

year old male with mesothelioma; Pleurectomy, PDT

Final Diagnosis

1. PREVIOUS BIOPSY SITE:

Fragment of skin showing foci of foreign body giant cell reaction to talc particles within the superficial and deep dermis.
Negative for malignancy.

2. RIGHT RIB:

Benign lamellar bone containing unremarkable bone marrow elements.
Asdherent striated muscle and fibroadipose tissue.
Negative for malignancy.

3. INTERNAL MAMMARY NODE:

One lymph node, positive for metastatic malignant mesothelioma (1/1).

4. PERICARDIAL LN FAT:

Four of six lymph nodes, positive for metastatic malignant mesothelioma (4/6).
Separate fragments of fibroadipose tissue containing nodular aggregate of malignant mesothelioma also identified.

5. MAJOR FISSURE:

Alveolar lung parenchyma with a focus of malignant mesothelioma.

6. POSTERIOR INTERCOSTAL NODE:

Seven of seven lymph nodes, positive for metastatic malignant mesothelioma (7/7).
Extranodal tumor extension also noted.

7. LUNG IMPLANT:

Nodular foci of malignant mesothelioma within the visceral pleura.
Tumor also involves the underlying lung parenchyma.
Separate fragments of fibroadipose tissue showing foci of malignant mesothelioma with adjacent talc granulomas.
Foci of lymphovascular invasion also noted.

8. LEVEL 7:

Nine of nine fragments of lymph node, positive for metastatic malignant mesothelioma.

9. LEVEL 9:

Five of five lymph nodes, positive for metastatic malignant mesothelioma (5/5).

CSCF ICD-O-3
Mesothelioma, epithelial NOS
path 9052/3
Mesothelioma, biphasic
9053/3
Site Pleura NOS
C38.4

Name:
MRN:

[page 2 of 8]
Name: [REDACTED]
MRN: [REDACTED]
Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected
Date Received:
Accession No. [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

10. LEVEL 8:

Fragments of fibroadipose tissue and blood clot.
Scattered detached clusters of malignant mesothelioma noted.
No lymph nodes identified.

11. LEVEL 10:

Two of two lymph nodes, positive for metastatic malignant mesothelioma (2/2).

12. HILAR NODE:

Two of 4 lymph nodes, positive for metastatic malignant mesothelioma (2/4).

13. LEVEL 4:

Three of 3 lymph nodes, positive for metastatic malignant mesothelioma (3/3).

14. LEVEL 2:

Blood clot, fibroadipose tissue and striated muscle containing a single detached cluster of malignant mesothelioma.

15. SUPERIOR MAMMARY NODE:

Fragments of lymph node, no tumor.

16. ANTERIOR HILAR NODE

One lymph node, positive for metastatic malignant mesothelioma (1/1).

17. POSTERIOR HILAR NODE:

One lymph node, positive for metastatic malignant mesothelioma (1/1).

18. PHRENIC NODE:

Five of 5 lymph nodes positive for metastatic malignant mesothelioma (5/5).
Extranodal tumor extension also noted.

19. DIAPHRAGM:

Fragments of fibroadipose tissue and striated muscle showing foci of malignant mesothelioma.
Foci of lymphovascular invasion also noted.

20. PERIESOPHAGEAL LN:

Nine of ten lymph nodes, positive for metastatic malignant mesothelioma (9/10).
Extranodal tumor extension also noted.

21. PERIAORTIC NODE:

Fragments of benign fibroadipose tissue and striated muscle.
No lymph nodes are identified.

Name [REDACTED]
MRN [REDACTED]

[page 3 of 8]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

22. ADD. DIAPHRAGM:

Fragments of fibroadipose tissue and striated muscle showing foci of malignant mesothelioma.

23. PERICARDIAL FAT:

Fragments of benign fibroadipose tissue.
Five lymph nodes, no tumor seen.

24. PHRENIC NERVE:

Fibroadipose tissue containing large nerve consistent with phrenic nerve.
A nodular focus of malignant mesothelioma noted within the fibroadipose tissue without invasion of nerve.

25. AZYGOS VEIN:

Fragments of fibroadipose tissue and large vessels.
Negative for malignancy.

26. PERICARDIUM TISSUE:

Fragments of fibroadipose tissue showing foci of malignant mesothelioma.

27. PERICARDIUM/DIAPHRAGM:

Malignant mesothelioma, biphasic type containing both epithelioid and sarcomatous component involving the mediastinal pleura, diaphragmatic pleura and a portion of lateral parietal pleura.
Inked pericardial resection margin is free of tumor.
Inked mediasternal fatty tissue margin is also free of tumor.
Inked diaphragmatic pleural resection margin is free of tumor.
Foci of lymphatic invasion also noted.

28. RADICAL PLEURECTOMY:

Fragments of fibroadipose tissue showing foci of malignant mesothelioma, biphasic type containing both sarcomatous and epithelioid components, see comment.
Foci of lymphatic invasion present.
Nodular foci of talc granulomas also noted.

The case material was reviewed and the report verified by: MD
(Electronic signature)
Verification Date:

Note

Immunostains are performed on block 28A with adequate controls. Tumor cells are positive for calretinin, CK5/6 and D2-40. Tumor cells are negative for TTF-1, WT-1 and CEA. These features are consistent with malignant mesothelioma.

Name: [REDACTED]
MRN: [REDACTED]

[page 4 of 8]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected:
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

See disclaimer:

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the

This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that are not directly confirmed by routine histopathologic internal or external control specimens.

Frozen Section Diagnosis

FS1A & 1B: Previous biopsy site. Skin and underlying soft tissue with focal presence of foreign body giant cells and mild chronic inflammation.

Called Received Reported

FS2: Major fissure: Lung parenchyma with focal presence of malignant tumor.

Called Received Reported

FS3: Diaphragm: Mesothelioma present.

Called Received Reported

Gross Description

The specimen is received in 28 parts in a container labeled with the patient's name and medical record number.

Specimen #1 is designated "previous biopsy site" and consists of a yellow tan skin fragment with attached adipose tissue. The skin measures 4.5 x 1.5 cm in surface dimension and 2.5 cm in depth. The previous incision site is gray tan and measures 2.0 cm in length. the cut surface of subcutaneous tissue is unremarkable. Representative section is submitted in three cassettes as follow: Cassette 1FS1A and 1FS1B from frozen section, 1c representative section of remaining skin.

Specimen #2 is designated "right rib" and consists of three gray tan rib fragments measuring from 5.0 cm to 6.5 cm in length and from 1.0 cm to 1.8 cm in diameter. The specimen has a minimal amount of soft tissue attached measuring from less than 0.1 cm to 0.6 cm. Representative section is submitted in cassette 2A after fixation and decalcification.

Name: [REDACTED]
MRN: [REDACTED]

[page 5 of 8]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected
Date Received:
Accession No. [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #3 is designated "internal mammary node" and consists of one yellow tan adipose tissue measuring 1.2 cm in greatest dimension. The specimen is bisected and submitted in cassette 3A.

Specimen #4 is designated "pericardial lymph node and fat" and consists of two yellow tan to gray tan adipose tissue fragments measuring 1.5 and 4.5 cm in greatest dimension. The specimen is interlaced with multiple white tan to gray tan rubbery firm lymph nodes measuring from 0.2 to 0.9 cm in greatest dimension. All lymph nodes and part of adipose tissue is submitted in cassette 4A.

Specimen #5 is designated "major fissure". The specimen is previously submitted for frozen section and consists of one purple tan to gray tan soft tissue fragments measuring 2.0 cm in greatest dimension. The specimen is submitted for permanent histological examination in cassette 5AFS2.

Specimen #6 is designated "posterior intercostal node" and consists of six gray tan to purple tan rubbery soft tissue fragments measuring 0.3 cm to 2.1 cm in greatest dimension. The specimen is submitted in cassettes 6A and 6B.

Specimen #7 is designated "lung implant" and consists of one purple tan to gray tan rubbery soft tissue fragment measuring 5.2 cm in greatest dimension. The cut surface of the specimen reveals multiple white tan to gray tan firm nodules measuring from 0.2 to 0.5 cm in greatest dimension. The specimen is submitted entirely in cassette 7A.

Specimen #8 is designated "level 7" and consists of multiple white tan to black tan rubbery soft tissue fragments measuring from 0.4 cm to 1.1 cm in greatest dimension. The specimen is submitted in cassette 8A.

Specimen #9 is designated "level 9" and consists of one white tan to purple tan rubbery soft tissue fragments measuring 3.5 cm in greatest dimension. The entire specimen is submitted in cassette 9A.

Specimen #10 is designated "level 8" and consists of one black tan to yellow tan soft tissue fragment measuring 1.6 cm in greatest dimension. The specimen is submitted in cassette 10A.

Specimen #11 is designated "level 10" and consists of two yellow tan adipose tissue measuring 0.5 cm and 1.5 cm in greatest dimension. The specimen is interlaced with gray tan to black tan rubbery lymph nodes measuring from 0.5 to 1.5 cm in greatest dimension. The specimen is submitted in cassette 11A.

Specimen #12 is designated "hilar node" and consists of two black tan rubbery soft tissue fragments measuring 0.8 and 1.7 cm in greatest dimension. The specimen is submitted in cassette 12A.

Specimen #13 is designated "level 4" and consists of one yellow tan adipose tissue fragment measuring 3.0 cm in greatest dimension, interlaced with multiple white tan to purple tan rubbery lymph node measuring from 0.3 to 1.2 cm in greatest dimension. The lymph nodes are submitted in cassette 13A.

Specimen #14. is designated "level 2" and consists of one hemorrhagic soft tissue fragment measuring 3.5 cm in greatest dimension. Representative sections are submitted in cassettes 14A and 14B.

Name: [REDACTED]
MRN: [REDACTED]

[page 6 of 8]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #15 is designated "superior mammary node" and consists of one yellow tan to gray tan rubbery soft tissue fragment measuring 2.1 cm in greatest dimension. The specimen is submitted in cassette 15A.

Specimen #16 is designated "anterior hilar node" and consists of one black tan rubbery soft tissue fragment measuring 0.4 cm in greatest dimension. The specimen is submitted in cassette 16A.

Specimen #17 is designated "posterior hilar node" and consists of one gray tan soft tissue fragment measuring 0.6 cm in greatest dimension. The specimen is submitted in cassette 17A.

Specimen #18 is designated "phrenic node" and consists of three yellow tan adipose tissue measuring from 0.5 to 1.9 cm in greatest dimension. The specimen is interlaced with multiple gray tan to purple tan rubbery lymph node measuring from 0.1 to 1.3 cm in greatest dimension. The lymph node is submitted in cassette 18A.

Specimen #19 is designated "diaphragm" and consists of one gray tan to pink tan membranous tissue measuring 2.9 cm in greatest dimension. The specimen is submitted in cassette 19B. Part of the specimen is submitted for frozen section. The remaining tissue of the frozen section is submitted for permanent histological examination in cassette 19AFS3.

Specimen #20 is designated "periesophageal LN" and consists of multiple yellow tan to purple tan rubbery soft tissue fragments measuring from 0.9 to 3.2 cm in greatest dimension. The specimen is submitted in cassette 20A to 20C.

Specimen #21 is designated "periaortic node" and consists of one yellow tan adipose tissue measuring 2.5 cm in greatest dimension. The specimen is submitted in cassette 21A.

Specimen #22 is designated "additional diaphragm" and consists of multiple white tan to purple tan muscular membranous tissue fragments measuring 6.0 x 5.0 x 1.0 cm in aggregate.. The representative sections are submitted in cassettes 22A to 22C.

Specimen #23 is designated "pericardial fat" and consists of one yellow tan lobulated adipose tissue measuring 4.5 x 2.5 x 1.2 cm. The specimen is interlaced with multiple small lymph nodes measuring from less than 0.1 cm to 0.4 cm in greatest dimension. Representative sections are submitted in cassette 23A.

Specimen #24 is designated "phrenic nerve" and consists of one gray tan to purple tan soft tissue fragment measuring 15.0 cm in length. The specimen is interlaced with one white tan nerve tissue. The specimen is submitted entirely in one cassette 24A.

Specimen #25 is designated "azygos vein" and consists of one blue tan to purple tan blood vessel fragment measuring 5.3 cm in length and 0.5 cm in diameter. The outer surface of the vessel is smooth and glistening with minimal amount of adipose tissue attached. Representative section is submitted in cassette 25A.

Specimen #26 is designated "pericardium tissue" and consists of one gray tan to purple tan soft tissue fragment measuring 3.2 cm in greatest dimension. The specimen is submitted in cassette 26A.

Name: [REDACTED]
MRN: [REDACTED]

[page 7 of 8]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received: [REDACTED]
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #27 is designated "pericardium/diaphragm" and consists of a cup shaped yellow tan soft tissue which contains the thickened pleura from the diaphragmatic site, the mediasternal pericardial site and a portion of lateral parietal pleura. There is no lung tissue identified within the specimen, only the thickened pleura is present. The pericardial site was stitched and there is a pink tan membranous peridial soft tissue present which measures 5.0 cm in greatest dimension. The diaphragmatic pleura consistent of white to reddish muscle at the surgical margin. The stitched pericardial membranous margin is inked blue, the mediasternal pleural fatty tissue margin is inked blue, the diaphragmatic pleura margin is in black. The specimen is serially sectioned. The cut surface of soft tissue has diffuse infiltrated tumor nodules measuring from 0.5 up to 4.0 cm in thickness. The tumor involves all the pleuras. Representative sections are submitted as follows:

27A-27C Tumor with membranous inked pericardial margin
27D-27E Tumor with inked mediasternal fat margin
27F-27H Tumor with inked diaphragmatic pleural margin

Specimen #28 is designated "radical pleurectomy" and consists of multiple gray tan to pink tan nodular pleural tissue measuring 22.0 x 10.0 cm in aggregate. The thickness measures from 1.0 cm to 2.0 cm. The cut surface of the specimen reveals multiple white tan to gray tan nodules measuring from 0.2 cm to 2.5 cm in greatest dimension. Representative section is submitted in cassette 28A to 28D.

Case reviewed with attending pathologist.

Dictated by [REDACTED] and [REDACTED] dictated by [REDACTED]

Dictated by:

Pathologist(s)

Name: [REDACTED]
MRN: [REDACTED]

*Pw TSS dx discrepancy from
TC6A specimen was epithelial only.*

Page 7 of 7 *342*

[page 8 of 8]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Mesothelioma -	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form		Provide the tumor identifier documented on the initial case quality control form for this case.
Pathologic Diagnosis Provided on Initial Pathology Report		Biphasic Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF		Epithelioid Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form		
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	Submitted specimen is Epithelioid	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file dc817ba5-d216-4463-892d-c94c8a9757bf (TCGA-TS-A7OY.6342557E-F0C7-499E-8726-6FF0533AE95F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).